Somatic mutation profile of tumor specimen TCGA-WB-A819-01A (aliquot TCGA-WB-A819-01A-11D-A35I-08) from TCGA case TCGA-WB-A819, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 36.2 years (13,233 days).
Specimen TCGA-WB-A819-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97094bf0-c5b1-4878-b0c1-6da834c0c6b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A819-10A (Blood Derived Normal), aliquot TCGA-WB-A819-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61673a61-24cf-4428-94ce-ba5cf15720fc

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RET | c.2753T>C p.M918T | Missense Mutation (SNP) | VAF 39/131 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs74799832, CM941246, COSV60685905; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HEXD | c.1319C>A p.P440Q (on ENST00000327949 / NM_001369487.1; = p.R470= on NM_173620.3) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV100028079; called by muse, mutect2, varscan2
- ZNF407 | c.6438C>G p.I2146M | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55270225; called by muse, mutect2, varscan2
- PRPF8 | c.3179A>G p.E1060G | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2
- SULF1 | c.2098C>T p.H700Y | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- DPM1 | c.693T>C p.F231= | Silent (SNP) | VAF 39/148 reads (26%) | called by muse, mutect2, varscan2
